Gene-level copy-number profile of tumor specimen TCGA-06-0877-01A from TCGA case TCGA-06-0877, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.7 years (28,760 days).
Specimen TCGA-06-0877-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.3bcc850a-56b2-4c8b-8edf-4cb69b79d9a3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0877-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/801ccf1e-51c2-427f-9621-88befce09bbe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 4,833; copy number 2: 40,138; copy number 3: 14,743; copy number 4: 32; copy number 35: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0877-01A-01D-0384-01): tumor purity 0.77, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,135,598–24,088,051, 67 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,721,724–55,211,628, 6 genes, copy number 35: AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.
- chr7:55,244,247–55,245,681, 1 gene, copy number 35: AC073324.1.

Autosomal genes at a single copy (total copy number 1): 2,446. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
